Somatic mutation profile of tumor specimen MP2PRT-PAUXHS-TBP1-A (aliquot MP2PRT-PAUXHS-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAUXHS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,026 days).
Specimen MP2PRT-PAUXHS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 679d356a-78fb-4010-b329-6b6f252fb5b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXHS-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXHS-NB1-B-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7de039a3-5304-4c8e-b8cb-2083db12bdd8

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 92/382 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs558210028, COSV54405409; called by muse, mutect2, varscan2
- ECH1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 93/390 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338794235; called by muse, mutect2, varscan2
- MAGEA3 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 148/643 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs376647411, COSV64755983; called by muse, mutect2, varscan2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2
- SPTBN5 | c.9767G>A p.R3256H | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs542201823, COSV58028174; called by muse, mutect2, varscan2
- TENM3 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.131); catalogued as rs1446772973, COSV101305442; called by mutect2, varscan2
- ANKRD30B | c.3602T>C p.L1201P | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2
- FSHR | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 121/479 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IGKJ1 | chr2:88861912 CCGAACGTCCACCACAGTGAGAGCT>A | Missense Mutation (DEL) | VAF 38/208 reads (18%) | called by pindel, varscan2*
- KIF5C | c.2211-3C>A | Splice Region (SNP) | VAF 62/259 reads (24%) | called by muse, mutect2, varscan2
- PPP6C | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 87/356 reads (24%) | called by muse, mutect2, varscan2
- FAT2 | c.9771C>T p.S3257= | Silent (SNP) | VAF 107/403 reads (27%) | catalogued as COSV55817540, COSV99943638; called by muse, mutect2, varscan2
- MCF2L | c.1212C>T p.A404= (on ENST00000375608; = p.A372= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/438 reads (19%) | catalogued as rs769071029, COSV65050630; called by muse, mutect2, varscan2
- PCDHGA8 | c.870G>A p.P290= | Silent (SNP) | VAF 57/260 reads (22%) | catalogued as rs370409157; called by muse, mutect2, varscan2
